Gene-level copy-number profile of tumor specimen TCGA-14-1451-01A from TCGA case TCGA-14-1451, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 39.4 years (14,401 days).
Specimen TCGA-14-1451-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.edb8039d-ddab-4129-809e-645176f12a91.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-14-1451-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1a0c69ab-954d-4a68-aeb4-a0fbd9ebc1c5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,924; copy number 2: 47,010; copy number 3: 3,819; copy number 4: 5; copy number 13: 9; copy number 26: 27; copy number 29: 5; copy number 30: 6; copy number 32: 1; copy number 35: 8; copy number 37: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-14-1451-01A-01D-0517-01): tumor purity 0.78, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 59 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:1,529,891–1,647,212, 2 genes, copy number 29 (within-gene range 3–29): WNT5B, FBXL14.
- chr12:57,693,955–57,984,761, 27 genes, copy number 26: OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr12:68,805,011–68,971,570, 6 genes, copy number 30 (within-gene range 1–30): AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM.
- chr13:27,424,619–27,794,768, 8 genes, copy number 13: GTF3A, MTIF3, RNU6-63P, LNX2, POLR1D, AL136439.1, NPM1P4, GSX1.
- chr13:27,828,763–27,828,869, 1 gene, copy number 13: RNU6-73P.
- chr13:34,925,834–36,131,382, 8 genes, copy number 35 (within-gene range 1–35): AL138690.1, NBEA, SCAND3P1, PHBP13, MAB21L1, AL390071.1, LINC00445, DCLK1.
- chr13:38,533,343–38,622,671, 3 genes, copy number 37: LINC00437, LINC00366, PRDX3P3.
- chr18:78,137,223–78,544,188, 4 genes, copy number 29–32: AC107892.1, AC087399.1, AC012572.1, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 6,537. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
